Gene-level copy-number profile of tumor specimen C3N-04176-07 from CPTAC case C3N-04176, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,173 days).
Specimen C3N-04176-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a9d7ec6-351c-4886-a3fb-924acdb8f95c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04176-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/094b6b1f-2a52-4e1d-8666-9c484a675337

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 17,112; copy number 2: 28,176; copy number 3: 11,228; copy number 4: 1,527; copy number 5: 287; copy number 6: 4; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–12,058,227, 11 genes (within-gene range 0–1): AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1.
- chr9:12,775,020–12,823,060, 1 gene (within-gene range 0–1): LURAP1L.
- chr9:21,403,081–22,455,740, 29 genes: IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr17:18,426,861–18,506,313, 8 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:75,941,507–76,027,306, 6 genes: ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL.
- chr18:11,326,270–11,552,847, 7 genes: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 293 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:28,548,135–28,809,291, 1 gene, copy number 5 (within-gene range 3–5): AC008825.1.
- chr5:28,808,538–29,396,095, 11 genes, copy number 5: AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064.
- chr8:115,408,496–135,656,722, 275 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:18,623,339–18,719,341, 4 genes, copy number 6: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,773,665–18,843,399, 2 genes, copy number 7 (within-gene range 1–11): GGT3P, AC008132.2.

Autosomal genes at a single copy (total copy number 1): 15,997. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
